Somatic mutation profile of tumor specimen TARGET-10-PANZEG-03A (aliquot TARGET-10-PANZEG-03A-01D) from TARGET case TARGET-10-PANZEG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (857 days).
Specimen TARGET-10-PANZEG-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d3c3f55-3919-41bc-97dd-9033b6ecc387.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANZEG-14A (Bone Marrow Normal), aliquot TARGET-10-PANZEG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2d9f83d-e9bb-4f84-8191-e08f0f68cb12

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 4, Frame Shift Ins 2, Silent 2, 5'UTR 1, Splice Site 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 26/60 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs779862368, COSV57050514; called by muse, mutect2, varscan2
- AKAP17A | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.714); catalogued as rs193269079; called by mutect2, varscan2
- DPY19L2 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs569045259; called by muse, mutect2, varscan2
- MAGEB2 | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100975650; called by muse, mutect2, varscan2
- OR10R2 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100936780; called by muse, mutect2, varscan2
- PCSK2 | c.1535C>T p.T512M | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs754916065, COSV99359588; called by muse, mutect2, varscan2
- BTAF1 | c.3813+1G>A p.X1271_splice | Splice Site (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- CDKN2A | c.152_153insAAGGT p.M52Rfs*3 | Frame Shift Ins (INS) | VAF 14/19 reads (74%) | called by mutect2, pindel, varscan2
- CDO1 | c.78dup p.E27* | Frame Shift Ins (INS) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- KCND2 | c.1419C>G p.S473R | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MDM1 | c.1069C>G p.R357G | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIOBP | c.4335G>A p.R1445= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs367990804; called by muse, mutect2, varscan2
- UTP20 | c.1383G>A p.S461= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as rs763457427, COSV55378308; called by muse, mutect2, varscan2
- BMP1 | c.2107+1720C>T | Intron (SNP) | VAF 32/184 reads (17%) | catalogued as rs528835024, COSV100109838; called by muse, mutect2, varscan2
- C2CD6 | c.1582-3984G>A | Intron (SNP) | VAF 19/32 reads (59%) | catalogued as rs752369478; called by muse, mutect2, varscan2
- CFAP58 | c.*61G>A | 3'UTR (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- DUS1L | c.398-106del | Intron (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- H3C7 | c.-2C>T | 5'UTR (SNP) | VAF 28/141 reads (20%) | catalogued as rs768155711; called by muse, mutect2, varscan2
- LINC01561 | n.394C>A | RNA (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- MTAP | c.691-121C>A | Intron (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
